Somatic mutation profile of tumor specimen TCGA-MT-A67F-01A (aliquot TCGA-MT-A67F-01A-11D-A30E-08) from TCGA case TCGA-MT-A67F, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 60.4 years (22,057 days).
Specimen TCGA-MT-A67F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a34d31b1-e6df-4b4a-af21-75333f4d01e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MT-A67F-10A (Blood Derived Normal), aliquot TCGA-MT-A67F-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/376c11d1-a232-4c83-a890-7ff65dc52094

The open-access MAF lists 315 somatic variants for this specimen: 244 protein-altering or splice-affecting, 66 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 212, Silent 66, Nonsense Mutation 25, Intron 3, Splice Region 2, Splice Site 2, Nonstop Mutation 2, 5'UTR 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVRL1 | c.1385C>G p.S462* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as rs1085307422, CM044558, COSV66359525; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAPK1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 12/78 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519911, COSV53184855, COSV99308005; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.543G>T p.K181N | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV51709101; called by muse, mutect2, varscan2
- ABCD3 | c.1282C>A p.P428T | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as COSV100931424; called by muse, mutect2, varscan2
- AC098582.1 | c.2759C>T p.S920L | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.063); catalogued as rs757313229, COSV99985806; called by muse, mutect2, varscan2
- ACO1 | c.117C>G p.I39M | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV100008395; called by muse, mutect2, varscan2
- ACOX1 | c.1057C>T p.H353Y | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV99503787; called by mutect2, varscan2
- ACTB | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.063); catalogued as rs1484491064, COSV59318696, COSV59320746; called by muse, mutect2, varscan2
- ACTL6B | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.929); catalogued as rs748105438, COSV50514457, COSV50514641; called by muse, mutect2, varscan2
- ACTN2 | c.2173G>C p.E725Q | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100856903; called by muse, mutect2, varscan2
- ADGRL4 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as COSV66064092; called by muse, mutect2, varscan2
- AFF1 | c.2047C>G p.L683V | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV100320895; called by muse, mutect2, varscan2
- AGPAT3 | c.1078G>C p.E360Q | Missense Mutation (SNP) | VAF 36/304 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.171); catalogued as COSV99377016, COSV99377709; called by muse, mutect2, varscan2
- AHNAK2 | c.1401G>C p.L467F | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV60907083; called by muse, mutect2, varscan2
- AK4 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV59200032; called by muse, mutect2, varscan2
- AK7 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.15); catalogued as rs755402172, COSV50871793, COSV99967417; called by muse, mutect2, varscan2
- AQP10 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759318252, COSV100270364; called by muse, mutect2, varscan2
- ARHGEF25 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); catalogued as rs974306796, COSV99678147; called by muse, mutect2, varscan2
- ARID2 | c.3470C>G p.S1157* | Nonsense Mutation (SNP) | VAF 22/148 reads (15%) | catalogued as COSV100536615, COSV57603040; called by muse, mutect2, varscan2
- ASB16 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.136); catalogued as COSV53236414; called by muse, mutect2, varscan2
- ASIC3 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs559456655, COSV52527314; called by muse, mutect2, varscan2
- ASXL2 | c.878C>G p.S293* | Nonsense Mutation (SNP) | VAF 23/159 reads (14%) | catalogued as COSV99710147, COSV99711704; called by muse, mutect2, varscan2
- ATM | c.6712G>C p.E2238Q | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV53738090, COSV99590756; called by muse, mutect2, varscan2
- ATP10B | c.1947G>C p.E649D | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs1169969429, COSV100515436; called by muse, mutect2, varscan2
- ATP2B3 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs782226811, COSV54843229, COSV99685268; called by muse, mutect2, varscan2
- ATXN7 | c.2661G>C p.Q887H | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs952961723, COSV99894891; called by muse, mutect2
- BBS5 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs931751345, COSV54752193; called by muse, mutect2
- BIRC6 | c.11896C>T p.H3966Y | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.284); catalogued as COSV101428504; called by muse, mutect2, varscan2
- BTBD6 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.986); catalogued as COSV59269172; called by muse, mutect2, varscan2
- C10orf53 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100935079; called by muse, mutect2
- C11orf68 | c.397C>G p.L133V (on ENST00000530188; = p.L174V on NM_031450.4) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.404); catalogued as COSV100437141; called by muse, mutect2, varscan2
- C14orf119 | c.422G>C p.*141Sext*1 | Nonstop Mutation (SNP) | VAF 4/100 reads (4%) | catalogued as COSV99399985; called by muse, mutect2
- C1GALT1C1 | c.363G>C p.M121I | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100485633; called by muse, mutect2, varscan2
- C1S | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.071); catalogued as COSV100196697; called by muse, mutect2, varscan2
- C2orf16 | c.325C>G p.P109A | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV101284405; called by muse, mutect2, varscan2
- C2orf16 | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV101284406; called by muse, mutect2, varscan2
- C4orf50 | c.133G>A p.E45K (on ENST00000324058; = p.E1277K on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs773324409, COSV60691345; called by muse, mutect2, varscan2
- CACNA1G | c.3350C>T p.P1117L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV100662206; called by muse, mutect2, varscan2
- CASP8 | c.697C>T p.R233W (on ENST00000432109 / NM_033355.3; = p.R250W on NM_001228.4) | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760898260, COSV51846938; called by muse, mutect2, varscan2
- CASP8 | c.943C>G p.L315V (on ENST00000432109 / NM_033355.3; = p.L332V on NM_001228.4) | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51849838, COSV99629590, COSV99630551; called by muse, mutect2, varscan2
- CBLL2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV60369891, COSV60370312; called by muse, mutect2, varscan2
- CCDC136 | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99922927; called by muse, mutect2, varscan2
- CCDC15 | c.1492C>G p.Q498E | Missense Mutation (SNP) | VAF 36/290 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs369886713; called by muse, varscan2
- CCDC184 | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 13/75 reads (17%) | catalogued as COSV100344016; called by muse, mutect2, varscan2
- CCDC71 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV100422400; called by muse, mutect2, varscan2
- CCDC86 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV57124459, COSV99920213; called by muse, mutect2
- CCKBR | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.102); catalogued as COSV58099916; called by muse, mutect2, varscan2
- CCNE2 | c.8G>A p.R3K | Missense Mutation (SNP) | VAF 38/321 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs750728492, COSV100353817; called by muse, mutect2, varscan2
- CDC27 | c.1036C>T p.L346F | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0.031); catalogued as COSV50536234, COSV99295770; called by muse, mutect2, varscan2
- CDH23 | c.9553G>A p.D3185N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.682); catalogued as COSV99822595; called by muse, mutect2, varscan2
- CDK13 | c.1867G>A p.D623N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV51705167, COSV99475856; called by muse, mutect2, varscan2
- CEP85 | c.1374G>C p.L458F | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99432672; called by muse, mutect2, varscan2
- CEP85 | c.1583G>C p.R528T | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV99432675; called by muse, mutect2
- CHMP4C | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV99794235; called by muse, mutect2, varscan2
- CHMP7 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs775480040, COSV100500675; called by muse, mutect2
- CNOT4 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 15/99 reads (15%) | catalogued as COSV100211937; called by muse, mutect2, varscan2
- CNTNAP1 | c.1175G>A p.W392* | Nonsense Mutation (SNP) | VAF 19/91 reads (21%) | catalogued as COSV99226769; called by muse, mutect2, varscan2
- COL18A1 | c.2714C>T p.P905L (on ENST00000359759 / NM_130444.3; = p.P670L on NM_030582.4) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100700826; called by muse, mutect2, varscan2
- COL24A1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as rs758503239, COSV65304236; called by muse, mutect2, varscan2
- COL6A1 | c.2615G>A p.R872Q | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as rs377586358; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPB1 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99999767; called by muse, mutect2
- CPS1 | c.2344C>T p.H782Y | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV99243626; called by muse, mutect2, varscan2
- CRYBG1 | c.3770C>G p.S1257C | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100954580, COSV64813062; called by muse, mutect2, varscan2
- CSMD3 | c.6515C>A p.S2172* (on ENST00000297405 / NM_001363185.1; = p.S2068* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99841471; called by muse, mutect2, varscan2
- CTNNBL1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV100799667; called by muse, mutect2, varscan2
- CTU2 | c.1202-1G>A p.X401_splice | Splice Site (SNP) | VAF 14/82 reads (17%) | catalogued as COSV99966289; called by muse, mutect2, varscan2
- CUL1 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV100296817; called by muse, mutect2, varscan2
- CUL9 | c.4225C>T p.R1409W | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs371581531; called by muse, mutect2, varscan2
- DHX16 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV100905226; called by muse, mutect2, varscan2
- DLGAP1 | c.1044C>G p.I348M | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100232662; called by muse, mutect2, varscan2
- DMD | c.9235C>T p.Q3079* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV58911937; called by muse, mutect2, varscan2
- DNAH11 | c.7038G>C p.L2346F | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV100179938; called by muse, mutect2, varscan2
- DNHD1 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV99600627; called by muse, mutect2, varscan2
- DNHD1 | c.1510G>C p.E504Q | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.777); catalogued as COSV54442830; called by muse, mutect2, varscan2
- DOP1B | c.6006G>C p.E2002D | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.996); catalogued as COSV101215656; called by muse, mutect2, varscan2
- DSPP | c.1412C>G p.S471C | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV99217685; called by muse, mutect2, varscan2
- EDC3 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV100166078, COSV59340515; called by muse, mutect2, varscan2
- EDC4 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 19/160 reads (12%) | catalogued as COSV99534520; called by muse, mutect2, varscan2
- ENDOV | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.12); catalogued as rs894438252, COSV100108599; called by muse, mutect2, varscan2
- ENOSF1 | c.449G>A p.R150K (on ENST00000340116 / NM_001354066.2; = p.R102K on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/446 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV99201068, COSV99201126; called by muse, mutect2, varscan2
- EXPH5 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.331); catalogued as COSV99761949; called by muse, mutect2
- FAM161B | c.1423C>T p.Q475* (on ENST00000651776; = p.Q412* on NM_152445.3) | Nonsense Mutation (SNP) | VAF 22/159 reads (14%) | catalogued as COSV99679876; called by muse, mutect2, varscan2
- FAM161B | c.1288C>T p.R430W (on ENST00000651776; = p.R367W on NM_152445.3) | Missense Mutation (SNP) | VAF 41/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200522428, COSV99679877; called by muse, mutect2, varscan2
- FBXO47 | c.1275G>C p.L425F | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.459); catalogued as COSV100960802; called by muse, mutect2
- FRMD3 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.281); catalogued as COSV100170999; called by muse, mutect2, varscan2
- GABRA6 | c.828G>A p.G276= | Splice Region (SNP) | VAF 18/151 reads (12%) | catalogued as COSV50879276; called by muse, mutect2, varscan2
- GFM2 | c.1837G>C p.E613Q | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV99714571; called by muse, mutect2, varscan2
- GNPTAB | c.2510C>G p.S837C | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV100172230; called by muse, mutect2, varscan2
- GOLPH3 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs192633198; called by muse, mutect2
- GPHA2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.386); catalogued as rs757236833, COSV99376312; called by muse, mutect2, varscan2
- GPRASP1 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 21/304 reads (7%) | catalogued as COSV100851044; called by muse, mutect2
- GUSB | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs752854143, COSV100512699; ClinVar: likely benign; called by muse, mutect2, varscan2
- H2AC4 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV52518212, COSV52518824; called by muse, mutect2, varscan2
- HCN1 | c.2638G>A p.D880N | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.031); catalogued as COSV100300418; called by muse, mutect2, varscan2
- HIP1 | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 27/553 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs782438239, COSV61188850; called by muse, mutect2
- HIP1 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV100417884; called by muse, mutect2, varscan2
- HNRNPCL1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); catalogued as COSV58610273; called by muse, mutect2, varscan2
- HOATZ | c.275G>C p.R92T | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100239553; called by muse, mutect2, varscan2
- HP1BP3 | c.1315G>C p.D439H | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV100391994; called by muse, mutect2, varscan2
- HUWE1 | c.12529G>A p.E4177K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53351298; called by muse, mutect2, varscan2
- IBTK | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 12/94 reads (13%) | catalogued as COSV100091128; called by muse, mutect2, varscan2
- IDH1 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.152); catalogued as COSV100577122; called by muse, mutect2, varscan2
- IFT81 | c.1528G>C p.E510Q | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV99656244; called by muse, mutect2, varscan2
- IKZF2 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 19/96 reads (20%) | catalogued as COSV100563715; called by muse, mutect2, varscan2
- IL31RA | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.046); catalogued as COSV99763380; called by muse, mutect2, varscan2
- INSRR | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.455); catalogued as COSV100947844; called by muse, mutect2, varscan2
- INTS7 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs1480156850, COSV100877543; called by muse, mutect2, varscan2
- IQGAP1 | c.480C>G p.F160L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV99185210; called by muse, mutect2
- IRS2 | c.3722G>C p.R1241T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101019260; called by muse, mutect2, varscan2
- JAG2 | c.3167G>A p.R1056Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.302); catalogued as rs376433872; called by muse, mutect2
- JMJD1C | c.4084G>C p.D1362H | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.553); catalogued as COSV100550731; called by muse, mutect2, varscan2
- KCNK9 | c.396G>A p.M132I | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV57279366; called by muse, mutect2
- KIF19 | c.1988C>G p.S663C | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV100739129, COSV63428756; called by muse, mutect2
- KIF6 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54675409; called by muse, mutect2
- KLHL42 | c.1067-1G>A p.X356_splice | Splice Site (SNP) | VAF 68/537 reads (13%) | catalogued as COSV101179817; called by muse, mutect2, varscan2
- LACC1 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100354731; called by muse, mutect2, varscan2
- LPIN3 | c.1798C>G p.Q600E | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV100182696; called by muse, mutect2
- LYG2 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as rs569037546, COSV100283722; called by muse, mutect2
- MAK | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57566070; called by muse, mutect2, varscan2
- MAP3K4 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs561816464, COSV100815287, COSV100815564; called by muse, mutect2, varscan2
- MAPKAP1 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as COSV99785399; called by muse, mutect2, varscan2
- MAST1 | c.657C>A p.F219L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV99263351; called by muse, mutect2, varscan2
- MAST4 | c.6205G>A p.E2069K (on ENST00000403625 / NM_001164664.2; = p.E1880K on NM_015183.3) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.044); catalogued as COSV99845048; called by muse, mutect2, varscan2
- MEA1 | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV99775829; called by muse, mutect2
- MED12 | c.5817G>C p.Q1939H | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.478); catalogued as rs1257997950, COSV61334250; called by muse, mutect2
- MED18 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 51/345 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100868953; called by muse, mutect2, varscan2
- MFSD1 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV99963976; called by muse, mutect2
- MID1 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 18/155 reads (12%) | catalogued as COSV100452606; called by muse, mutect2, varscan2
- MINPP1 | c.488C>G p.S163W | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100916778, COSV64355631; called by muse, mutect2, varscan2
- MRPS23 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs941624314, COSV58032008; called by muse, mutect2
- MSH2 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 61/467 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as HM030031, COSV99254307; called by muse, mutect2, varscan2
- MTBP | c.2159G>C p.G720A | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs1206429956, COSV100012386, COSV59967863; called by muse, mutect2, varscan2
- MUC16 | c.21972G>A p.M7324I | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.003); catalogued as COSV101200576; called by muse, mutect2, varscan2
- MYCBP2 | c.12832G>C p.E4278Q (on ENST00000357337; = p.E4316Q on NM_015057.5) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100631088; called by muse, mutect2, varscan2
- MYO1C | c.423G>C p.E141D (on ENST00000648651 / NM_001080779.2; = p.E106D on NM_033375.5) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100704474; called by muse, mutect2, varscan2
- MYOM2 | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316996365, COSV50707353; called by muse, mutect2, varscan2
- NAGPA | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | PolyPhen benign (0.058); catalogued as COSV100392778, COSV100393025; called by muse, mutect2, varscan2
- NAT10 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99140307; called by muse, mutect2
- NBEA | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV59798007; called by muse, mutect2
- NBEA | c.3235G>A p.E1079K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.956); catalogued as COSV100082458; called by muse, mutect2, varscan2
- NCBP1 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100912642; called by muse, mutect2, varscan2
- NCKAP5 | c.4736A>G p.D1579G | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV100493523; called by muse, mutect2, varscan2
- NCOR1 | c.3242C>T p.P1081L | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as rs1237541182, COSV51994234; called by muse, mutect2, varscan2
- NES | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as rs747164825, COSV100957939; called by muse, mutect2, varscan2
- NFIX | c.686G>A p.R229K | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV100666573; called by muse, mutect2, varscan2
- NGLY1 | c.1395G>A p.W465* | Nonsense Mutation (SNP) | VAF 16/150 reads (11%) | catalogued as COSV99770732; called by muse, varscan2
- NIPBL | c.7569G>T p.M2523I | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs755159074, COSV99241762; called by muse, mutect2, varscan2
- NLRP6 | c.2595G>C p.K865N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.108); catalogued as COSV100380935, COSV100381072; called by muse, mutect2
- NUP210 | c.4524G>C p.W1508C | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99596645; called by muse, mutect2, varscan2
- NUP93 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as COSV100360104; called by muse, mutect2, varscan2
- NUP93 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.123); catalogued as rs1351843162, COSV100360379; called by muse, mutect2, varscan2
- NUP93 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100360381; called by muse, mutect2, varscan2
- OR2S2 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs750682972, COSV59529677; called by muse, mutect2, varscan2
- PADI3 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.106); catalogued as rs1045296474, COSV64934768; called by muse, mutect2
- PAXIP1 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as rs751250291, COSV101249928; called by muse, mutect2, varscan2
- PCDHA5 | c.591A>T p.K197N | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as COSV100972458; called by muse, mutect2, varscan2
- PCDHGA1 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as rs747495549, COSV100966028, COSV65297976; called by muse, mutect2, varscan2
- PLCE1 | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.445); catalogued as COSV99596182; called by muse, mutect2, varscan2
- PLEKHA7 | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs367885889; called by muse, mutect2, varscan2
- PLPP1 | c.587G>A p.R196K | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV53304603, COSV99301895; called by muse, mutect2, varscan2
- POMK | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV100505919; called by muse, mutect2, varscan2
- PPDPF | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as rs1569005580, COSV100925645; called by muse, mutect2, varscan2
- PPP4R1 | c.688C>T p.R230* (on ENST00000400556 / NM_001042388.3; = p.R213* on NM_005134.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV53284126; called by muse, mutect2
- PRPF40B | c.1123G>A p.E375K (on ENST00000380281; = p.E369K on NM_012272.3) | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV99980020; called by muse, mutect2, varscan2
- PTEN | c.686C>A p.S229* | Nonsense Mutation (SNP) | VAF 13/141 reads (9%) | catalogued as CM110118, COSV64290316, COSV64291916, COSV64310910; called by muse, mutect2, varscan2
- PWWP2B | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV100535887; called by muse, mutect2, varscan2
- RAD52 | c.465C>A p.L155= | Splice Region (SNP) | VAF 26/234 reads (11%) | catalogued as COSV99942636; called by muse, mutect2, varscan2
- RANBP2 | c.6485G>C p.R2162T | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV99312759; called by muse, mutect2
- RANBP2 | c.6862G>A p.G2288R | Missense Mutation (SNP) | VAF 35/349 reads (10%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as COSV99312761; called by muse, mutect2, varscan2
- RAP2C | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 61/330 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100747360; called by muse, mutect2, varscan2
- REEP1 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV99383120; called by muse, mutect2, varscan2
- RETSAT | c.755C>G p.S252C | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99806146; called by muse, mutect2, varscan2
- RIMBP2 | c.3150C>A p.F1050L | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV99900032; called by muse, mutect2, varscan2
- RNF121 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100683636; called by muse, mutect2, varscan2
- RNF4 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 35/320 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58642179; called by muse, mutect2, varscan2
- RP1L1 | c.2723C>T p.S908L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV101223447; called by muse, mutect2, varscan2
- RSL1D1 | c.617C>G p.S206C | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100852005, COSV63078487; called by muse, mutect2, varscan2
- RUBCN | c.1945G>C p.E649Q | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.278); catalogued as COSV99584626; called by muse, mutect2, varscan2
- SART1 | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV100409097; called by muse, mutect2
- SEC31B | c.3031G>A p.E1011K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.072); catalogued as COSV100947390; called by muse, mutect2, varscan2
- SERPINE2 | c.579G>A p.W193* | Nonsense Mutation (SNP) | VAF 10/75 reads (13%) | catalogued as COSV99296890; called by muse, mutect2, varscan2
- SHC1 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1324411446, COSV58316178; called by muse, mutect2, varscan2
- SIPA1L1 | c.4519C>T p.Q1507* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100665809; called by muse, mutect2, varscan2
- SIPA1L3 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99727294; called by muse, mutect2, varscan2
- SIRPB2 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); catalogued as COSV63123446; called by muse, mutect2, varscan2
- SLC25A33 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as rs944594500, COSV100235833; called by muse, mutect2, varscan2
- SLC32A1 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.121); catalogued as COSV99462515; called by muse, mutect2
- SLC39A12 | c.1399C>G p.L467V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV101070096, COSV66201035; called by muse, mutect2
- SMARCA1 | c.818T>G p.F273C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100946641; called by muse, mutect2, varscan2
- SMARCA4 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV100758910; called by muse, mutect2, varscan2
- SMU1 | c.987G>C p.Q329H | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV101238559, COSV68139501; called by muse, mutect2
- SNX16 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100629576, COSV100629668; called by muse, mutect2, varscan2
- SNX20 | c.950G>C p.*317Sext*87 | Nonstop Mutation (SNP) | VAF 22/138 reads (16%) | catalogued as COSV100319278; called by muse, mutect2, varscan2
- SPAG17 | c.814C>T p.L272F | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs755510464, COSV100309856; called by muse, mutect2, varscan2
- SPATA7 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139160202, COSV99248208; called by muse, mutect2, varscan2
- SPTBN4 | c.1341G>C p.E447D | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100151606; called by muse, mutect2, varscan2
- SPTLC1 | c.471G>C p.K157N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV99364978; called by muse, varscan2
- SSX2IP | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100642668; called by muse, mutect2, varscan2
- STK17A | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777075015, COSV100082229; called by muse, mutect2, varscan2
- STRC | c.4612C>G p.L1538V | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV55852403, COSV55853142; called by muse, mutect2, varscan2
- STX18 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as COSV60372203; called by muse, mutect2
- SZT2 | c.4203G>C p.Q1401H (on ENST00000634258 / NM_001365999.1; = p.Q1344H on NM_015284.4) | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as COSV100987510; called by muse, mutect2, varscan2
- TAF1L | c.4387G>A p.E1463K | Missense Mutation (SNP) | VAF 93/280 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.795); catalogued as COSV99645092; called by muse, mutect2, varscan2
- TAF2 | c.2825C>T p.S942F | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); catalogued as COSV100978769; called by muse, mutect2, varscan2
- TBC1D22A | c.973C>G p.L325V | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100453464; called by muse, mutect2, varscan2
- TET3 | c.1921C>T p.Q641* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99996505; called by muse, mutect2, varscan2
- TFAP2A | c.181C>T p.P61S (on ENST00000482890; = p.P53S on NM_001032280.3) | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV100117086; called by muse, mutect2, varscan2
- THSD7A | c.3172C>T p.R1058C | Missense Mutation (SNP) | VAF 52/369 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70263651; called by muse, mutect2, varscan2
- TIMM21 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV99400161; called by muse, mutect2, varscan2
- TMC2 | c.1917G>C p.L639F | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV100727775; called by muse, mutect2, varscan2
- TMEM50B | c.117G>A p.W39* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as COSV101336672; called by muse, mutect2, varscan2
- TMTC4 | c.1774C>T p.R592C (on ENST00000376234 / NM_001350577.2; = p.R611C on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs1430665035, COSV60891405; called by muse, mutect2, varscan2
- TNPO2 | c.1579T>C p.F527L | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV100790389; called by muse, mutect2, varscan2
- TRAPPC9 | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101228172; called by muse, mutect2
- TRIM5 | c.137C>G p.S46C | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100000492; called by muse, mutect2, varscan2
- TRIML2 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.152); catalogued as COSV100456216; called by muse, mutect2, varscan2
- TSKS | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99883491; called by muse, mutect2, varscan2
- TTLL12 | c.459C>G p.F153L | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV99333631; called by muse, mutect2, varscan2
- TTN | c.23029G>A p.V7677M (on ENST00000591111; = p.V6750M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/159 reads (7%) | PolyPhen benign (0.001); catalogued as rs779653609, COSV59960825; called by muse, mutect2
- UBR5 | c.7387G>C p.D2463H | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV99641654; called by muse, mutect2, varscan2
- UBXN7 | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99581506; called by muse, mutect2
- UFL1 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV100990113; called by muse, mutect2, varscan2
- UHRF1BP1L | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99691914; called by muse, mutect2
- USF3 | c.3686C>G p.S1229* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | catalogued as COSV100325582; called by muse, mutect2
- USH2A | c.10031C>G p.S3344C | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100238807, COSV100238978; called by muse, mutect2, varscan2
- USP49 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.336); catalogued as COSV99790459; called by muse, mutect2, varscan2
- USP9X | c.2608G>T p.E870* | Nonsense Mutation (SNP) | VAF 5/85 reads (6%) | catalogued as COSV100199809; called by muse, mutect2
- VPS13D | c.12523G>C p.E4175Q | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.331); catalogued as COSV99167721; called by muse, mutect2, varscan2
- WDR49 | c.1099G>C p.E367Q (on ENST00000308378 / NM_001366158.1; = p.E708Q on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100393401, COSV57713045; called by muse, mutect2
- WDR81 | c.4072G>A p.D1358N (on ENST00000409644 / NM_001163809.2; = p.D307N on NM_152348.4) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100489069; called by muse, mutect2, varscan2
- WDSUB1 | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100701855; called by muse, mutect2, varscan2
- WFDC13 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs183041894, COSV100225188; called by muse, mutect2, varscan2
- XPO6 | c.1561G>C p.E521Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV58964953; called by muse, mutect2, varscan2
- YIF1B | c.920G>A p.W307* (on ENST00000339413 / NM_001039673.3; = p.W292* on NM_001039671.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100008010; called by muse, mutect2, varscan2
- ZFC3H1 | c.4288T>C p.Y1430H | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.039); catalogued as COSV101110629; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV100460307; called by muse, mutect2
- ZNF197 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100482175; called by muse, mutect2
- ZNF385D | c.617G>T p.C206F | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99875652; called by muse, mutect2, varscan2
- ZNF585A | c.1312C>G p.H438D (on ENST00000292841 / NM_001288800.2; = p.H383D on NM_152655.3) | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99493388; called by muse, mutect2, varscan2
- ZNF750 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53959616, COSV53962745; called by muse, mutect2
- AL359922.1 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- C2orf16 | c.239C>G p.S80C | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2
- FANCM | c.5930T>C p.L1977S | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SYNRG | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- AHNAK | c.14379C>T p.F4793= | Silent (SNP) | VAF 59/431 reads (14%) | catalogued as rs1272978572, COSV57206510, COSV57226377; called by muse, mutect2, varscan2
- ASXL1 | c.1383G>C p.L461= | Silent (SNP) | VAF 32/223 reads (14%) | catalogued as COSV100040435; called by muse, mutect2, varscan2
- C2CD6 | c.33C>T p.F11= | Silent (SNP) | VAF 9/131 reads (7%) | catalogued as COSV99633900; called by muse, mutect2
- C2orf80 | c.387C>T p.L129= | Silent (SNP) | VAF 43/278 reads (15%) | catalogued as COSV100378529; called by muse, mutect2, varscan2
- C5orf51 | c.384G>T p.L128= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV101069020; called by muse, mutect2, varscan2
- CACNA1C | c.1023C>T p.H341= | Silent (SNP) | VAF 20/234 reads (9%) | catalogued as rs375785714; called by muse, mutect2
- CAPN15 | c.3135C>T p.I1045= | Silent (SNP) | VAF 18/142 reads (13%) | catalogued as COSV99562676; called by muse, mutect2, varscan2
- CASKIN2 | c.3027C>T p.F1009= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as rs753890852, COSV58599072; called by muse, mutect2, varscan2
- CC2D1A | c.438C>G p.L146= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV100528611; called by muse, mutect2, varscan2
- CDK5R1 | c.426C>T p.V142= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as COSV99912560; called by muse, mutect2, varscan2
- CHRNB1 | c.1505G>A p.*502= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV100043565; called by muse, mutect2, varscan2
- CLSTN3 | c.1416C>T p.L472= | Silent (SNP) | VAF 45/359 reads (13%) | catalogued as rs1027608950, COSV99867378; called by muse, mutect2, varscan2
- CSNK1E | c.237G>C p.V79= | Silent (SNP) | VAF 11/113 reads (10%) | catalogued as COSV100725064; called by muse, mutect2
- EFNA3 | c.576C>T p.I192= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100860856; called by muse, mutect2, varscan2
- FAT2 | c.1080C>G p.L360= | Silent (SNP) | VAF 21/149 reads (14%) | catalogued as rs1269864082, COSV99943674; called by muse, mutect2, varscan2
- FITM1 | c.192C>T p.V64= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as COSV99246395; called by muse, mutect2, varscan2
- FLT4 | c.1914G>C p.L638= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV99988040; called by muse, mutect2, varscan2
- G0S2 | c.150C>T p.F50= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100884473; called by muse, mutect2
- GABRA1 | c.396G>A p.K132= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV50099491, COSV50101391; called by muse, mutect2
- HADHA | c.1113G>C p.L371= | Silent (SNP) | VAF 22/380 reads (6%) | catalogued as COSV101023771; called by muse, mutect2
- HAUS6 | c.2142C>T p.F714= | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as COSV100997877; called by muse, varscan2
- HLA-DQB1 | c.567C>T p.I189= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as rs937512024, COSV100891060; called by muse, mutect2, varscan2
- HSPBAP1 | c.1242G>C p.G414= | Silent (SNP) | VAF 21/191 reads (11%) | catalogued as COSV100063637; called by muse, mutect2, varscan2
- ISM2 | c.1665C>T p.N555= | Silent (SNP) | VAF 13/162 reads (8%) | catalogued as rs763077922, COSV99376775; called by muse, mutect2
- ITPR3 | c.2391C>G p.V797= | Silent (SNP) | VAF 18/160 reads (11%) | catalogued as COSV100967754; called by muse, mutect2, varscan2
- KDM8 | c.210G>A p.V70= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as COSV99619795; called by muse, mutect2
- KRTAP10-10 | c.252C>T p.C84= | Silent (SNP) | VAF 31/221 reads (14%) | catalogued as COSV100554715; called by muse, mutect2, varscan2
- MATR3 | c.1692G>T p.V564= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV100735273; called by muse, mutect2, varscan2
- MEAK7 | c.693C>T p.V231= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV100640421; called by muse, mutect2, varscan2
- MLLT10 | c.2949C>T p.L983= (on ENST00000307729 / NM_001195626.3; = p.L999= on NM_004641.3) | Silent (SNP) | VAF 19/150 reads (13%) | catalogued as COSV100308483; called by muse, mutect2, varscan2
- MYO5A | c.81G>A p.L27= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV100697936; called by muse, mutect2, varscan2
- NES | c.1809G>C p.V603= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV100957941; called by muse, mutect2
- OPLAH | c.2082C>T p.I694= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV101470802; called by muse, mutect2, varscan2
- OR4B1 | c.424C>T p.L142= | Silent (SNP) | VAF 19/134 reads (14%) | catalogued as COSV100535620, COSV58883397; called by muse, mutect2, varscan2
- PABPC1L | c.1158C>T p.L386= | Silent (SNP) | VAF 45/358 reads (13%) | catalogued as COSV99408004; called by muse, mutect2, varscan2
- PARP14 | c.5040C>G p.L1680= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV101506321; called by muse, mutect2, varscan2
- PCGF2 | c.60C>T p.L20= | Silent (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- PDE4DIP | c.5214C>A p.S1738= | Silent (SNP) | VAF 11/143 reads (8%) | catalogued as COSV100520641; called by muse, mutect2
- PLIN5 | c.429G>A p.L143= | Silent (SNP) | VAF 31/249 reads (12%) | catalogued as COSV101113603; called by muse, mutect2, varscan2
- POGZ | c.4077G>C p.L1359= | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as COSV99305126; called by muse, mutect2
- POU4F3 | c.531C>T p.L177= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV100047164, COSV57944767; called by muse, mutect2
- PRAMEF12 | c.1161C>T p.L387= | Silent (SNP) | VAF 28/255 reads (11%) | catalogued as rs770473280, COSV100743447; called by muse, mutect2, varscan2
- PRDM1 | c.1029C>T p.P343= | Silent (SNP) | VAF 13/135 reads (10%) | catalogued as COSV100958907; called by muse, mutect2
- PRPS1 | c.126G>A p.V42= | Silent (SNP) | VAF 45/253 reads (18%) | catalogued as COSV100978882; called by muse, mutect2, varscan2
- PSD4 | c.2157G>A p.G719= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV99831315; called by muse, mutect2, varscan2
- PTPRO | c.1866C>T p.D622= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as COSV99841234; called by muse, mutect2, varscan2
- RETREG3 | c.1302C>T p.P434= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV99519024; called by muse, mutect2, varscan2
- SLC12A3 | c.1629C>T p.I543= | Silent (SNP) | VAF 23/194 reads (12%) | catalogued as COSV52632180, COSV99344535; called by muse, mutect2, varscan2
- SLC25A25 | c.201C>T p.V67= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV100895833; called by muse, mutect2, varscan2
- SLC37A4 | c.1152C>T p.F384= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV58155311; called by muse, mutect2
- STOML1 | c.27G>C p.A9= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99167669; called by muse, mutect2
- STRC | c.4860C>T p.F1620= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs1210507748, COSV100294621; called by muse, mutect2
- THBD | c.852G>C p.A284= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV101001909, COSV65702646; called by muse, varscan2
- THEG | c.321C>T p.I107= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as COSV100700636; called by muse, mutect2, varscan2
- TLR7 | c.696C>G p.L232= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV101028020; called by muse, mutect2, varscan2
- TOM1L2 | c.1104C>T p.V368= (on ENST00000379504 / NM_001350333.2; = p.V318= on NM_001033551.3) | Silent (SNP) | VAF 23/180 reads (13%) | catalogued as COSV100541154; called by muse, mutect2, varscan2
- TRAV34 | c.288C>T p.I96= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs1358328722; called by muse, mutect2, varscan2
- TRIP12 | c.2188C>T p.L730= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV99390692; called by muse, mutect2
- TTC3 | c.2898G>A p.L966= | Silent (SNP) | VAF 18/141 reads (13%) | catalogued as COSV100695804; called by muse, mutect2, varscan2
- UCKL1 | c.780C>A p.V260= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100700539; called by muse, mutect2, varscan2
- URGCP | c.330T>G p.V110= (on ENST00000453200 / NM_001077663.3; = p.V101= on NM_017920.4) | Silent (SNP) | VAF 9/125 reads (7%) | catalogued as COSV99787650; called by muse, mutect2
- XKR6 | c.1752C>G p.L584= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV100440961; called by muse, mutect2, varscan2
- XPR1 | c.948C>G p.L316= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100851495; called by muse, mutect2
- ZNF148 | c.1569G>A p.L523= | Silent (SNP) | VAF 25/186 reads (13%) | catalogued as rs1449474976, COSV100642147; called by muse, mutect2, varscan2
- ZNF91 | c.153C>T p.F51= | Silent (SNP) | VAF 17/159 reads (11%) | catalogued as COSV100323221; called by muse, mutect2, varscan2
- ZNRD2 | c.102C>T p.I34= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV100326165, COSV57079477; called by muse, mutect2, varscan2
- AC116366.2 | c.-638+10881C>T | Intron (SNP) | VAF 44/309 reads (14%) | catalogued as COSV61819406, COSV61820003; called by muse, mutect2, varscan2
- ARHGAP6 | c.589-35720G>A | Intron (SNP) | VAF 20/122 reads (16%) | catalogued as rs997698253, COSV100498698; called by muse, mutect2, varscan2
- CFAP47 | c.5536-635G>T | Intron (SNP) | VAF 12/95 reads (13%) | catalogued as COSV100545577, COSV57971805; called by muse, mutect2, varscan2
- RNU7-174P | chr8:80559677 C>T | 5'Flank (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- ZNF436 | c.-134G>T | 5'UTR (SNP) | VAF 9/87 reads (10%) | catalogued as COSV100011223; called by muse, mutect2, varscan2
